Gene-level copy-number profile of tumor specimen TCGA-QK-A8Z8-01A from TCGA case TCGA-QK-A8Z8, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: G2; Age at diagnosis: 60.5 years (22,107 days).
Specimen TCGA-QK-A8Z8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.3228bd74-d265-43e7-8de4-c05af961af60.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QK-A8Z8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9dd7e6f4-0c0d-4172-ad43-c2561d00f131

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,347; copy number 2: 43,858; copy number 3: 3,975; copy number 5: 109; copy number 7: 376; copy number 11: 40; copy number 15: 33; copy number 18: 16; copy number 20: 48; copy number 31: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QK-A8Z8-01A-11D-A390-01): tumor purity 0.7, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 632 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:48,660,125–57,837,046, 216 genes, copy number 5–31 (broad region; genes not listed).
- chr8:38,105,493–38,144,076, 1 gene, copy number 11 (within-gene range 1–11): ASH2L.
- chr8:38,123,274–39,580,134, 39 genes, copy number 11: AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1.
- chr18:47,390–15,330,282, 376 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,347. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
